Somatic mutation profile of tumor specimen TCGA-KH-A6WC-01A (aliquot TCGA-KH-A6WC-01A-11D-A33E-09) from TCGA case TCGA-KH-A6WC, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IA; Tumor grade: GX; Age at diagnosis: 82.6 years (30,167 days).
Specimen TCGA-KH-A6WC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9506a424-895e-4bf8-ad55-728acbab1873.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KH-A6WC-10B (Blood Derived Normal), aliquot TCGA-KH-A6WC-10B-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b495985-bb39-499d-a1dc-360f5c6153e8

The open-access MAF lists 14 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Silent 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAD1 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV56643964; called by muse, mutect2
- NOTCH1 | c.5167+2T>C p.X1723_splice | Splice Site (SNP) | VAF 17/130 reads (13%) | catalogued as COSV53036554; called by muse, mutect2, varscan2
- PCDHA6 | c.1412G>A p.G471D | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs542651929, COSV65341784; called by muse, mutect2, varscan2
- RYR3 | c.6106G>A p.E2036K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66785642; called by muse, mutect2
- SETBP1 | c.4367G>A p.R1456H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56320000; called by muse, mutect2
- SLC17A6 | c.1547G>T p.C516F | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV54137645; called by muse, mutect2
- HEG1 | c.2966G>C p.C989S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KMT2D | c.11224C>T p.Q3742* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- PCDHB11 | c.767T>C p.I256T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2
- PRTN3 | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2
- SLX4 | c.1427C>A p.S476Y | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.862); called by muse, mutect2
- TSPAN6 | c.618G>C p.E206D | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.378); called by muse, mutect2
- UBE4B | c.2704G>T p.A902S (on ENST00000343090 / NM_001105562.3; = p.A773S on NM_006048.5) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2
- SNED1 | c.3471G>T p.A1157= | Silent (SNP) | VAF 6/99 reads (6%) | called by muse, mutect2
